Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6511, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6511-01A (Primary Tumor).

Examination: **Histopathological examination (cito)**

Material: **Total organ resection – rectum**

TCGA – EI – 6511

Physician in charge:

Material collected on:

Material received on:

Expected time of examination

Clinical diagnosis:

Examination performed on

Macroscopic description:

16.4 cm length of the large intestine with the whole mesorectum fat tissue of 2.5 cm in thickness. An ulcerous tumour sized 4,2 x 6.7 x 1.1 cm found in the mucosa. The lesion covers 100% of the intestine circumference, located 7.1 cm from one of the cut lines and 3.4 cm from the opposite one. Minimum side margin is 0,2 cm.

Microscopic description:

Adenocarcinoma tubulopapillare (G2). Infiltratio carcinomatosa telae adiposae mesorecti. Intestine ends free of neoplastic lesions. Metastases carcinomatosa in lymphonodis (No IV/XVIII).

Histopathological diagnosis:

Adenocarcinoma tubulopapillare. Tubulopapillar adenocarcinoma of the rectum.

Metastases carcinomatosa in lymphonodis regionalis (No IV/XVIII). Cancer metastases in regional lymph nodes. (G2; Dukes C, Astler-Coller C2; pN1; R0).

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file a2136961-3ace-4164-8289-8a3cf8ad9707 (TCGA-EI-6511.F92E38C9-C682-4665-9DAF-3675ECC570EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).